Somatic mutation profile of tumor specimen TCGA-2Z-A9JS-01A (aliquot TCGA-2Z-A9JS-01A-21D-A42J-10) from TCGA case TCGA-2Z-A9JS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.1 years (27,053 days).
Specimen TCGA-2Z-A9JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fa39000-81d9-4724-b768-3871d15bcbcd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JS-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JS-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b2de8a1-19cc-4852-8cd9-9e30ef7cddf2

The open-access MAF lists 130 somatic variants for this specimen: 98 protein-altering or splice-affecting, 32 silent.
By variant classification: Missense Mutation 76, Silent 32, Frame Shift Del 10, Nonsense Mutation 6, In Frame Del 2, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.921C>A p.N307K | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99366262; called by muse, mutect2, varscan2
- ACSS3 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699191; called by muse, mutect2, varscan2
- ADCY3 | c.3380C>T p.T1127I | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99568711; called by muse, mutect2, varscan2
- AGA | c.832A>T p.R278* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV99219615; called by muse, mutect2, varscan2
- AKT1S1 | c.554C>A p.P185H (on ENST00000344175 / NM_001098633.4; = p.P205H on NM_032375.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100465497; called by muse, mutect2, varscan2
- ANAPC7 | c.733T>A p.F245I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV101484794; called by muse, mutect2, varscan2
- ANKRD34B | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100103591; called by muse, mutect2, varscan2
- ARHGAP24 | c.1574A>C p.Q525P (on ENST00000395184 / NM_001025616.3; = p.Q432P on NM_031305.3) | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV99982227; called by muse, mutect2, varscan2
- ARNTL | c.1574C>T p.T525M (on ENST00000403290 / NM_001297719.2; = p.T524M on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.556); catalogued as rs774861185, COSV100724805; called by muse, mutect2, varscan2
- ASIC4 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs909316143, COSV100761828; called by muse, varscan2
- ATP8B4 | c.2842C>A p.L948M | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as rs1222775837, COSV52711899; called by muse, mutect2, varscan2
- BICC1 | c.1792C>A p.H598N | Missense Mutation (SNP) | VAF 151/336 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as COSV99570051, COSV99570741; called by muse, mutect2, varscan2
- BNIPL | c.15A>T p.Q5H | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.28); catalogued as COSV99639741; called by muse, mutect2, varscan2
- BRD8 | c.967G>A p.A323T (on ENST00000254900 / NM_139199.2; = p.A396T on NM_006696.4) | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.541); catalogued as COSV99137288; called by muse, mutect2
- BTAF1 | c.1359del p.L454* | Frame Shift Del (DEL) | VAF 132/324 reads (41%) | catalogued as COSV56431699; called by mutect2, varscan2
- CHERP | c.458A>T p.D153V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV99550383; called by muse, mutect2, varscan2
- CLPTM1L | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100307088, COSV100307203; called by muse, mutect2, varscan2
- CNTN4 | c.2870C>A p.S957* | Nonsense Mutation (SNP) | VAF 123/142 reads (87%) | catalogued as COSV100639471, COSV61868445; called by muse, mutect2, varscan2
- COL5A1 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as CM128976, COSV100880202; called by muse, mutect2, varscan2
- CPT1C | c.1334G>C p.G445A | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.919); catalogued as COSV99773550; called by muse, mutect2, varscan2
- CPVL | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99606159; called by muse, mutect2, varscan2
- DAAM2 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV51302930; called by muse, mutect2, varscan2
- DENND4B | c.4102T>G p.W1368G | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100768795; called by muse, mutect2, varscan2
- DIP2B | c.2810C>A p.T937K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99998927; called by muse, varscan2
- DIP2C | c.3533T>C p.I1178T | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV99792788; called by muse, mutect2, varscan2
- DNHD1 | c.12620T>A p.L4207H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600588; called by muse, mutect2, varscan2
- DOT1L | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV101288737; called by muse, mutect2, varscan2
- DPCD | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100924312; called by muse, mutect2, varscan2
- EDC3 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100166068; called by muse, mutect2, varscan2
- EEF1A2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 57/90 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV99419623; called by muse, mutect2, varscan2
- ELP2 | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100626973; called by muse, mutect2, varscan2
- ENO2 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99980426; called by muse, mutect2, varscan2
- ETS1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100091057; called by muse, mutect2, varscan2
- FBLN1 | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as COSV99411031; called by muse, mutect2, varscan2
- HCN3 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as COSV100712969; called by muse, mutect2, varscan2
- HDAC11 | c.236A>C p.Y79S | Missense Mutation (SNP) | VAF 80/105 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849992; called by muse, mutect2, varscan2
- INPP5E | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV99259409; called by muse, mutect2, varscan2
- MACF1 | c.134G>C p.W45S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100485502; called by muse, mutect2, varscan2
- MKRN3 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV100091400; called by muse, mutect2
- MLC1 | c.988A>G p.K330E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100286460; called by muse, varscan2
- MST1R | c.1153T>C p.C385R | Missense Mutation (SNP) | VAF 61/69 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619217; called by muse, mutect2, varscan2
- MTMR11 | c.290A>G p.D97G (on ENST00000439741 / NM_001145862.2; = p.D25G on NM_181873.3) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100809141; called by muse, mutect2, varscan2
- MYO9A | c.5256-1G>C p.X1752_splice | Splice Site (SNP) | VAF 37/83 reads (45%) | catalogued as COSV100613937; called by muse, mutect2, varscan2
- MYT1 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100115081; called by muse, mutect2, varscan2
- NCKIPSD | c.833C>G p.T278S | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99584080; called by muse, mutect2, varscan2
- NR2E1 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934587; called by muse, mutect2, varscan2
- OGFR | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.55); catalogued as COSV51699894, COSV99284294; called by muse, mutect2, varscan2
- OLFM1 | c.1184C>T p.T395M (on ENST00000371793 / NM_001282611.2; = p.T377M on NM_014279.5) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174360762, COSV99423727; called by muse, mutect2, varscan2
- PCK1 | c.1163A>G p.N388S | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1418324682, COSV100100696; called by muse, mutect2
- PDIA2 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs933047026, COSV99250093; called by muse, mutect2, varscan2
- PNKD | c.510_511insG p.T171Dfs*13 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | catalogued as COSV99282537; called by mutect2, pindel, varscan2
- POLD2 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99788946; called by muse, mutect2, varscan2
- POLH | c.1540T>C p.S514P | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100947828; called by muse, mutect2, varscan2
- PRKAR2B | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV99708465; called by muse, mutect2, varscan2
- PRPF39 | c.1109A>T p.E370V | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV100866026, COSV63276766; called by muse, mutect2, varscan2
- PSMD12 | c.786A>T p.K262N | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100635387; called by muse, mutect2, varscan2
- PTPRB | c.561T>A p.N187K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.306); catalogued as COSV100547548; called by muse, mutect2, varscan2
- RAB14 | c.70A>T p.K24* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV100868772; called by muse, mutect2, varscan2
- RAI14 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV99463984; called by muse, mutect2, varscan2
- RANBP2 | c.2893A>G p.N965D | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV51706028, COSV99312700; called by muse, mutect2, varscan2
- RHOBTB3 | c.1613A>C p.K538T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV101183229; called by muse, mutect2, varscan2
- RYR1 | c.12609G>C p.Q4203H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100616370; called by muse, mutect2, varscan2
- SASS6 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99790974; called by muse, mutect2, varscan2
- SCAF1 | c.1876A>T p.R626W | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100862231; called by muse, mutect2, varscan2
- SEC22C | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 68/79 reads (86%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV99827560; called by muse, mutect2, varscan2
- SEPTIN12 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as COSV99190811; called by muse, mutect2, varscan2
- SLC27A3 | c.1885T>A p.Y629N (on ENST00000271857; = p.Y501N on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99670046; called by muse, mutect2, varscan2
- SLC3A2 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV58604156; called by muse, mutect2, varscan2
- SLC9A4 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV99763336; called by muse, mutect2, varscan2
- SLF2 | c.3426C>G p.D1142E | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV53271895, COSV99489454; called by muse, mutect2, varscan2
- SVEP1 | c.4036G>A p.V1346I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376449068; called by muse, mutect2, varscan2
- SYCP3 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.304); catalogued as COSV99901717; called by muse, mutect2, varscan2
- THEMIS | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs781331744, COSV100965351; called by muse, mutect2, varscan2
- TMEM131L | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99547810; called by muse, mutect2, varscan2
- TMEM30B | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100855751; called by muse, mutect2, varscan2
- TMPRSS6 | c.2409A>G p.*803Wext*96 | Nonstop Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100695992; called by muse, mutect2, varscan2
- TNFRSF11A | c.1493A>G p.D498G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99500407; called by muse, mutect2, varscan2
- TNRC6A | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs750057251, COSV59364582; called by muse, mutect2, varscan2
- UCP2 | c.238A>G p.N80D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as COSV60104523; called by muse, mutect2, varscan2
- UNC13A | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99408992; called by muse, varscan2
- UNC13D | c.2715A>C p.E905D | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99257141; called by muse, mutect2, varscan2
- VPS26A | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99697660; called by muse, mutect2, varscan2
- WDFY3 | c.3168-1G>A p.X1056_splice | Splice Site (SNP) | VAF 130/370 reads (35%) | catalogued as COSV99884570; called by muse, mutect2, varscan2
- WDR77 | c.313T>A p.L105M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99330901; called by muse, mutect2, varscan2
- WNT9B | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99255281; called by muse, mutect2
- ZNF778 | c.2177A>T p.E726V | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100124511; called by muse, mutect2, varscan2
- DNAAF2 | c.1844_1848del p.V615Efs*12 | Frame Shift Del (DEL) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- ELN | c.1182del p.P395Lfs*79 | Frame Shift Del (DEL) | VAF 74/154 reads (48%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.2561C>A p.S854* | Nonsense Mutation (SNP) | VAF 50/75 reads (67%) | called by mutect2, varscan2
- GPATCH8 | c.2554_2559del p.R855_S856del | In Frame Del (DEL) | VAF 42/71 reads (59%) | called by mutect2, pindel, varscan2
- LRP2 | c.8427_8429del p.N2810del | In Frame Del (DEL) | VAF 22/46 reads (48%) | called by pindel, varscan2
- MAP2 | c.4289del p.P1430Lfs*16 | Frame Shift Del (DEL) | VAF 132/364 reads (36%) | called by mutect2, pindel, varscan2
- NOTCH4 | c.4096_4109del p.Q1366Gfs*25 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | called by mutect2, varscan2
- PDK2 | c.547_551del p.A183Sfs*15 | Frame Shift Del (DEL) | VAF 38/162 reads (23%) | called by mutect2, pindel, varscan2
- PDLIM4 | c.343del p.T115Pfs*45 | Frame Shift Del (DEL) | VAF 66/166 reads (40%) | called by mutect2, pindel, varscan2
- PXDNL | c.437del p.L146Rfs*3 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | called by mutect2, pindel, varscan2
- RGL2 | c.1274del p.G425Vfs*12 | Frame Shift Del (DEL) | VAF 47/135 reads (35%) | called by mutect2, pindel, varscan2
- SLC7A9 | c.784del p.L262Wfs*2 | Frame Shift Del (DEL) | VAF 52/162 reads (32%) | called by mutect2, pindel, varscan2
- AIFM3 | c.591G>T p.V197= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV100104820; called by muse, mutect2, varscan2
- ANK3 | c.12357C>T p.I4119= (on ENST00000280772 / NM_001320874.2; = p.I640= on NM_001149.3) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99781132; called by muse, mutect2, varscan2
- ANKS3 | c.1950G>A p.G650= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs369166637; called by muse, mutect2, varscan2
- AP2B1 | c.1764T>C p.I588= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as COSV99251448; called by muse, mutect2, varscan2
- ARID1A | c.843G>A p.A281= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs752424350, COSV100252507; ClinVar: likely benign; called by muse, mutect2
- BIRC6 | c.10833T>C p.A3611= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV101428489; called by muse, mutect2, varscan2
- C9orf85 | c.264A>G p.P88= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100595100; called by muse, mutect2, varscan2
- CECR2 | c.3363G>A p.P1121= (on ENST00000342247 / NM_001290047.2; = p.P937= on NM_001290046.1) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs960677521, COSV52843611; called by muse, mutect2, varscan2
- CMYA5 | c.10239T>A p.R3413= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV101484205; called by muse, mutect2, varscan2
- DYRK2 | c.654G>T p.V218= (on ENST00000344096 / NM_006482.3; = p.V145= on NM_003583.4) | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100165345; called by muse, mutect2, varscan2
- EDC3 | c.1221C>T p.V407= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV59341142; called by muse, mutect2, varscan2
- FAT1 | c.7776T>C p.N2592= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV101499467; called by muse, mutect2, varscan2
- FEM1C | c.1533T>C p.T511= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99174392; called by muse, mutect2, varscan2
- FURIN | c.1995C>T p.H665= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs763946374, COSV51576047; called by muse, mutect2, varscan2
- GPANK1 | c.150T>C p.D50= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100789030; called by muse, mutect2, varscan2
- HARBI1 | c.549A>G p.R183= | Silent (SNP) | VAF 48/105 reads (46%) | catalogued as COSV100365889; called by muse, mutect2, varscan2
- HECTD4 | c.6888A>G p.L2296= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV66386613; called by muse, mutect2, varscan2
- HSP90AA1 | c.330C>T p.I110= | Silent (SNP) | VAF 58/142 reads (41%) | catalogued as rs759018453, COSV99355399; called by muse, mutect2, varscan2
- INO80 | c.285A>G p.T95= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV62741740; called by muse, mutect2, varscan2
- LIMS1 | c.600C>T p.I200= | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as rs758889895, COSV100185914; called by muse, mutect2, varscan2
- MAB21L4 | c.90G>C p.A30= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100278600; called by muse, mutect2, varscan2
- PCSK1 | c.381T>C p.N127= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100227191; called by muse, mutect2, varscan2
- PYHIN1 | c.706A>C p.R236= | Silent (SNP) | VAF 17/217 reads (8%) | catalogued as COSV100932379; called by muse, mutect2
- RC3H2 | c.933A>G p.K311= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100106773; called by muse, mutect2
- SIGLEC11 | c.2061A>G p.Q687= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs111614885; called by muse, mutect2, varscan2
- SNX14 | c.126C>A p.S42= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV100121680; called by muse, mutect2, varscan2
- SP3 | c.528C>T p.I176= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs769641050, COSV100022065; called by muse, mutect2, varscan2
- STOX1 | c.2826A>G p.T942= | Silent (SNP) | VAF 80/202 reads (40%) | catalogued as COSV100058069; called by muse, mutect2, varscan2
- TBC1D24 | c.630G>A p.A210= | Silent (SNP) | VAF 95/320 reads (30%) | catalogued as rs776459372, COSV53548286; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TMEM19 | c.234G>A p.G78= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99877046; called by muse, mutect2, varscan2
- UMODL1 | c.591T>A p.L197= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV101248683; called by muse, mutect2, varscan2
- ZZZ3 | c.2379A>G p.K793= | Silent (SNP) | VAF 103/215 reads (48%) | catalogued as rs943581641, COSV100890388; called by muse, mutect2, varscan2
